Somatic mutation profile of tumor specimen TCGA-CF-A47X-01A (aliquot TCGA-CF-A47X-01A-31D-A23U-08) from TCGA case TCGA-CF-A47X, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 60.8 years (22,200 days).
Specimen TCGA-CF-A47X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd4b9fff-45c8-4bba-9e20-d7e267a9e0e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A47X-10A (Blood Derived Normal), aliquot TCGA-CF-A47X-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f25097cf-dcaa-4852-9272-6cba7bcf554d

The open-access MAF lists 354 somatic variants for this specimen: 262 protein-altering or splice-affecting, 82 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 82, Nonsense Mutation 26, Splice Site 6, Intron 5, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 2, 5'UTR 2, RNA 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 35/53 reads (66%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 21/38 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99971864; called by muse, mutect2, varscan2
- AASDH | c.1629G>T p.L543F | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.786); catalogued as COSV99221179; called by muse, mutect2, varscan2
- ACP4 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54518366; called by mutect2, varscan2
- ACTL8 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs768803261, COSV64862417; called by muse, mutect2, varscan2
- ADAMTSL1 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV52822175; called by muse, mutect2, varscan2
- AHNAK2 | c.2889C>A p.S963R | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV60926102; called by muse, mutect2, varscan2
- AMY1A | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751946952, COSV64411062; called by muse, mutect2, varscan2
- ANKRD11 | c.4594G>T p.E1532* | Nonsense Mutation (SNP) | VAF 38/50 reads (76%) | catalogued as COSV99969100; called by muse, varscan2
- AP2A2 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV59963244; called by muse, mutect2, varscan2
- APOBEC3H | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs201348583, COSV62379062; called by muse, mutect2, varscan2
- ARHGAP27 | c.1927G>C p.E643Q (on ENST00000428638 / NM_001282290.1; = p.E302Q on NM_199282.3) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV65358455; called by muse, mutect2, varscan2
- ARHGEF3 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 57/120 reads (48%) | catalogued as COSV99575255; called by muse, mutect2, varscan2
- ARMCX2 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs782114404, COSV57530855; called by muse, mutect2, varscan2
- ASIC1 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0.166); catalogued as COSV57319683; called by muse, mutect2, varscan2
- AUP1 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51211756; called by muse, mutect2, varscan2
- AURKC | c.484G>C p.V162L (on ENST00000302804 / NM_001015878.2; = p.V128L on NM_003160.3) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57139676; called by muse, mutect2, varscan2
- BFSP1 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64901491; called by muse, mutect2, varscan2
- BPIFB1 | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV99487340; called by muse, mutect2
- BRD4 | c.1038G>C p.K346N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV54592312; called by muse, mutect2, varscan2
- C16orf78 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV54557906; called by muse, mutect2, varscan2
- C3 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55579091; called by muse, mutect2, varscan2
- C4BPB | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54692454; called by muse, mutect2, varscan2
- CACNG4 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50927027; called by muse, mutect2, varscan2
- CALCRL | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV66474767, COSV66476698; called by muse, mutect2, varscan2
- CASP7 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61881061, COSV61882912; called by muse, mutect2, varscan2
- CASP7 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61882927; called by muse, mutect2, varscan2
- CCDC38 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV60184375; called by muse, mutect2, varscan2
- CD180 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV56519363; called by muse, mutect2, varscan2
- CDCA7 | c.403G>C p.E135Q (on ENST00000347703 / NM_145810.3; = p.E214Q on NM_031942.5) | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV60721424; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1662G>A p.M554I (on ENST00000357886 / NM_001365728.1; = p.M540I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV59428432; called by muse, mutect2, varscan2
- CFAP36 | c.48C>G p.I16M | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59117536, COSV59117710; called by muse, mutect2, varscan2
- CFAP65 | c.3500C>G p.T1167S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58565229; called by muse, mutect2, varscan2
- CMSS1 | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV101375575; called by muse, mutect2, varscan2
- CMTR1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV65091478; called by muse, mutect2, varscan2
- COL11A2 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as COSV59501094; called by muse, mutect2, varscan2
- COL17A1 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs140872949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.3046G>C p.V1016L | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV55103287, COSV99797452; called by muse, mutect2, varscan2
- CPA1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV50571460; called by muse, mutect2, varscan2
- CREBBP | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 44/72 reads (61%) | catalogued as COSV52120786; called by muse, mutect2, varscan2
- CREM | c.644C>G p.S215* (on ENST00000429130; = p.S182* on NM_181571.3) | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100415160; called by muse, mutect2, varscan2
- CRTC2 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs551248341, COSV57845128; called by muse, mutect2, varscan2
- CRYBG3 | c.6118G>A p.E2040K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51711894; called by muse, mutect2, varscan2
- CSMD2 | c.3459T>G p.V1153= | Splice Region (SNP) | VAF 12/47 reads (26%) | catalogued as COSV53947942; called by muse, mutect2, varscan2
- CSMD3 | c.4657C>T p.Q1553* (on ENST00000297405 / NM_001363185.1; = p.Q1449* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | catalogued as COSV52140936; called by muse, mutect2, varscan2
- CTCF | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV50500877; called by muse, mutect2, varscan2
- CTNND1 | c.1981C>T p.Q661* (on ENST00000399050 / NM_001085458.2; = p.Q655* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV62384828; called by muse, mutect2
- DACT3 | c.1680C>G p.F560L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs746752006, COSV56261026; called by muse, mutect2
- DCPS | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs772776014, COSV55012087; called by muse, mutect2, varscan2
- DDB2 | c.590C>G p.S197* | Nonsense Mutation (SNP) | VAF 35/102 reads (34%) | catalogued as COSV99921604; called by muse, mutect2, varscan2
- DENND2A | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV52056922; called by muse, mutect2, varscan2
- DENND5B | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as COSV60906721; called by muse, mutect2, varscan2
- DEPTOR | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53820407; called by muse, mutect2, varscan2
- DESI2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55642603; called by muse, mutect2, varscan2
- DGKK | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV65709120; called by muse, mutect2, varscan2
- DHDDS | c.798G>C p.K266N (on ENST00000236342 / NM_001319959.1; = p.K267N on NM_024887.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV52578075; called by muse, mutect2, varscan2
- DLC1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52321462; called by muse, mutect2, varscan2
- DMRT3 | c.1003C>G p.R335G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV51907430; called by muse, mutect2, varscan2
- DMXL2 | c.1558C>G p.L520V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51853420; called by muse, mutect2, varscan2
- DNAH10 | c.11425G>C p.D3809H (on ENST00000409039; = p.D3748H on NM_207437.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101292196; called by muse, mutect2, varscan2
- DNAH10 | c.11527G>A p.E3843K (on ENST00000409039; = p.E3782K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV68999230; called by muse, mutect2, varscan2
- DNAH11 | c.4348A>T p.K1450* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100178997; called by muse, mutect2, varscan2
- DNAH3 | c.4784C>G p.S1595C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54543343; called by muse, mutect2, varscan2
- DNAH5 | c.10594G>A p.G3532S | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54245056; called by muse, mutect2, varscan2
- DNAI4 | c.1221G>T p.M407I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1488114143, COSV100925273, COSV64020768; called by muse, mutect2
- DPYD | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV64609964; called by muse, mutect2, varscan2
- DVL3 | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57457817; called by muse, mutect2, varscan2
- EDRF1 | c.2680G>C p.E894Q (on ENST00000356792 / NM_001202438.2; = p.E860Q on NM_015608.2) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.054); catalogued as COSV61765746; called by muse, mutect2, varscan2
- EFCAB3 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as rs552441218; called by muse, mutect2
- EIF4G3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99944065; called by muse, mutect2, varscan2
- ELF3 | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV100668733; called by muse, mutect2, varscan2
- ELF3 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs750329636, COSV62838337, COSV62839839; called by muse, mutect2, varscan2
- ELF3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV62839857; called by muse, mutect2, varscan2
- EPS8L1 | c.2083G>T p.E695* (on ENST00000201647 / NM_133180.3; = p.E568* on NM_017729.3) | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99136079; called by muse, mutect2, varscan2
- ERN1 | c.2591G>A p.R864K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV70504198; called by muse, varscan2
- ERN1 | c.2543G>C p.R848T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV70504203; called by muse, varscan2
- EVI2A | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 57/122 reads (47%) | catalogued as COSV99907577; called by muse, mutect2, varscan2
- EZH2 | c.1672C>G p.P558A (on ENST00000460911 / NM_001203247.2; = p.P563A on NM_004456.5) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV57460117; called by muse, mutect2, varscan2
- FAM166A | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61118507; called by muse, mutect2, varscan2
- FANCD2 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771078251, CS072195, COSV55044323, COSV99811915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO42 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs763594734, COSV65046627; called by muse, mutect2, varscan2
- FLG | c.11641G>C p.E3881Q | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.072); catalogued as COSV64246399; called by muse, mutect2, varscan2
- FLYWCH1 | c.733G>A p.E245K (on ENST00000253928 / NM_001308068.2; = p.E244K on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs747714881, COSV99558789; called by muse, varscan2
- FRY | c.7775C>T p.S2592L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV66576716; called by muse, mutect2, varscan2
- FTCD | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs552877652, COSV52428470; called by muse, mutect2, varscan2
- GATM | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as COSV67540955; called by muse, mutect2, varscan2
- GGTLC2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.208); catalogued as rs774440959, COSV101312216; called by muse, mutect2, varscan2
- GOLGA1 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65228917, COSV65230774; called by muse, mutect2, varscan2
- GPR4 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59917922; called by muse, mutect2, varscan2
- GPSM1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as COSV52518242; called by muse, mutect2, varscan2
- GRIK3 | c.2092-1G>A p.X698_splice | Splice Site (SNP) | VAF 8/14 reads (57%) | catalogued as COSV66145060; called by muse, mutect2, varscan2
- GTF3C1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs766261512, COSV55189032; called by muse, mutect2, varscan2
- HEATR5A | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1271861145, COSV66340326; called by muse, mutect2
- HEATR5B | c.5204C>T p.S1735L | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51854808; called by muse, mutect2, varscan2
- HEXIM1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60177454; called by muse, mutect2, varscan2
- HIVEP3 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV56017039, COSV56021277, COSV99913969; called by muse, mutect2, varscan2
- HMCES | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV59115977; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.100G>A p.E34K (on ENST00000354667 / NM_031243.3; = p.E22K on NM_002137.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV61160179; called by muse, mutect2, varscan2
- HSP90AA1 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53490731; called by muse, mutect2, varscan2
- HTR1B | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV64051728; called by muse, mutect2, varscan2
- IARS2 | c.2752-1G>C p.X918_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV56962963; called by muse, mutect2, varscan2
- IL9R | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV54898922, COSV54901623; called by muse, mutect2, varscan2
- INHBB | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs1054158512, COSV54677625; called by muse, mutect2, varscan2
- INO80 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV62741588; called by muse, mutect2, varscan2
- IPO4 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0.044); catalogued as COSV61017934; called by muse, mutect2, varscan2
- ITGB3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs760480847, COSV71383470; called by muse, mutect2, varscan2
- JCAD | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV64761220; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV59827375; called by muse, mutect2, varscan2
- KCNJ10 | c.880T>A p.C294S | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63634732; called by muse, mutect2, varscan2
- KCNJ14 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV57309796, COSV57310285; called by muse, mutect2, varscan2
- KDSR | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.383); catalogued as COSV58507776; called by muse, mutect2, varscan2
- KEL | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV62335761, COSV62337117; called by muse, mutect2, varscan2
- KIR3DL2 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs745524198, COSV99551998; called by muse, mutect2, varscan2
- LAMA1 | c.6775-1G>C p.X2259_splice | Splice Site (SNP) | VAF 38/77 reads (49%) | catalogued as COSV67542537; called by muse, mutect2, varscan2
- LAMA1 | c.2174C>G p.S725C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV67542542; called by muse, mutect2, varscan2
- LAMA3 | c.7230G>C p.L2410F (on ENST00000313654 / NM_198129.4; = p.L801F on NM_000227.6) | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV52540735; called by muse, mutect2, varscan2
- LAMB2 | c.4768G>A p.A1590T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59736654; called by muse, mutect2, varscan2
- LAMB2 | c.4291G>C p.E1431Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV59736664; called by muse, mutect2, varscan2
- LATS1 | c.1328C>G p.S443* | Nonsense Mutation (SNP) | VAF 73/153 reads (48%) | catalogued as COSV99485829; called by muse, mutect2, varscan2
- LENG8 | c.1063A>C p.K355Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs745665119, COSV58729712; called by muse, mutect2, varscan2
- LINGO1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.691); catalogued as rs774158790, COSV62438064; called by muse, mutect2, varscan2
- LRMDA | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV65281493; called by muse, mutect2, varscan2
- LRRC43 | c.1869C>G p.I623M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV57337191; called by muse, mutect2, varscan2
- LRRC7 | c.1251-1G>T p.X417_splice (on ENST00000651989 / NM_001370785.2; = p.X384_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/38 reads (24%) | catalogued as COSV50563440, COSV50598539; called by muse, mutect2, varscan2
- LRRK1 | c.5050G>A p.E1684K | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV52600760; called by muse, mutect2, varscan2
- LURAP1L | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV59985929; called by muse, mutect2, varscan2
- MACF1 | c.20181G>C p.E6727D (on ENST00000372915; = p.E4772D on NM_012090.5) | Missense Mutation (SNP) | VAF 58/103 reads (56%) | catalogued as COSV57137560; called by muse, mutect2, varscan2
- MAP4 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64243583; called by muse, mutect2, varscan2
- MIPOL1 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100538574; called by muse, mutect2, varscan2
- MLKL | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV58206192; called by muse, mutect2, varscan2
- MME | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs1382290757, COSV64706617, COSV64709552; called by muse, mutect2, varscan2
- MOB1B | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100511518; called by muse, mutect2
- MOCOS | c.2167C>G p.Q723E | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54341615, COSV54345296, COSV54346774; called by muse, mutect2, varscan2
- MON1A | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as COSV56559379; called by muse, mutect2, varscan2
- MORF4L1 | c.280G>A p.E94K (on ENST00000331268 / NM_206839.2; = p.E55K on NM_006791.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58705384; called by muse, mutect2, varscan2
- MRPL11 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs933300664, COSV60599430; called by muse, mutect2, varscan2
- MSMP | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as rs780563187, COSV65240230; called by muse, mutect2, varscan2
- MTHFR | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.122); catalogued as COSV56742432; called by muse, mutect2, varscan2
- MX1 | c.729C>A p.I243= | Splice Region (SNP) | VAF 20/40 reads (50%) | catalogued as COSV55820491; called by muse, varscan2
- MYH15 | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV56317146; called by muse, mutect2, varscan2
- MYH8 | c.5593C>T p.L1865F | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV67970591; called by muse, mutect2, varscan2
- MYLK | c.5338C>T p.P1780S | Missense Mutation (SNP) | VAF 108/193 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV60618880; called by muse, mutect2, varscan2
- NDUFS3 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99772302; called by muse, mutect2
- NEB | c.11878C>G p.L3960V | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV51447427; called by muse, mutect2, varscan2
- NMT1 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV51962006; called by muse, mutect2, varscan2
- NPHP1 | c.1791G>C p.M597I (on ENST00000393272 / NM_207181.4; = p.M598I on NM_000272.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57210871; called by muse, mutect2, varscan2
- NUAK1 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.268); catalogued as rs769881661, COSV54606978; called by muse, mutect2, varscan2
- OBSCN | c.9310G>T p.D3104Y | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52813253; called by muse, mutect2, varscan2
- OLFML2B | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV54195824; called by muse, mutect2, varscan2
- OPHN1 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 16/18 reads (89%) | catalogued as COSV100830390; called by muse, mutect2, varscan2
- OR10G7 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57868367; called by muse, mutect2, varscan2
- OR4C46 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60220788, COSV60220861; called by muse, mutect2, varscan2
- OR5D16 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65721599, COSV65722679; called by muse, mutect2, varscan2
- OTOF | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1178069041, COSV55514772; called by muse, mutect2, varscan2
- PAPOLA | c.1221G>C p.K407N | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV53484210; called by muse, mutect2, varscan2
- PARD3B | c.3280del p.V1094* (on ENST00000406610 / NM_001302769.2; = p.V1025* on NM_057177.7) | Frame Shift Del (DEL) | VAF 46/102 reads (45%) | catalogued as COSV62525425; called by mutect2, pindel, varscan2
- PARP14 | c.3698C>T p.S1233F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV71735382; called by muse, mutect2, varscan2
- PCDH9 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV60579811; called by muse, mutect2, varscan2
- PCDHA7 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs782122239, COSV65336202; called by muse, mutect2, varscan2
- PCF11 | c.2192C>G p.S731* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100018226; called by muse, mutect2, varscan2
- PER2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs769778637, COSV54523696; called by muse, mutect2, varscan2
- PICALM | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV62672157; called by muse, mutect2, varscan2
- PIK3C2A | c.2105C>G p.S702* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs1440351705, COSV99790613; called by muse, mutect2
- PLEK | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.991); catalogued as COSV52253367, COSV52253719; called by muse, mutect2, varscan2
- PNPLA2 | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60745000, COSV60745467; called by muse, mutect2, varscan2
- PNPT1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV53179303; called by muse, mutect2, varscan2
- PPARGC1B | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58528277, COSV58532373; called by muse, mutect2, varscan2
- PPP2CB | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV55329261; called by muse, mutect2, varscan2
- PRDX3 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100045382, COSV53720256; called by muse, mutect2, varscan2
- PSME4 | c.3586G>C p.D1196H | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66366933; called by muse, mutect2, varscan2
- PTPRF | c.4754C>T p.S1585L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs768112017, COSV100740847; called by muse, mutect2
- PTTG1IP | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 13/17 reads (76%) | catalogued as rs1569325989, COSV100445872, COSV58366015; called by muse, mutect2, varscan2
- PVALB | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV53413081; called by muse, mutect2
- RAB25 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63108704; called by muse, mutect2
- RALGAPA2 | c.2089C>T p.L697F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV52507416; called by muse, mutect2, varscan2
- RB1CC1 | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 126/158 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs750998543, COSV50260252; called by muse, mutect2, varscan2
- RELN | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1452632737, COSV59026898; called by muse, mutect2, varscan2
- RHOT1 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV61717800; called by muse, mutect2, varscan2
- RIN3 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV53653948; called by muse, mutect2, varscan2
- RIOK2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299944; called by muse, varscan2
- RIOX2 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57724430; called by muse, mutect2, varscan2
- RIPOR2 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV52427418; called by muse, mutect2, varscan2
- SAE1 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778336657, COSV54297933; called by muse, mutect2, varscan2
- SAP18 | c.242G>C p.R81T (on ENST00000607003; = p.R100T on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66822926; called by muse, mutect2, varscan2
- SHB | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs764015202, COSV66630173; called by muse, mutect2, varscan2
- SHOC2 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV54623841; called by muse, mutect2, varscan2
- SLAIN2 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (1); PolyPhen possibly damaging (0.88); catalogued as rs779619766, COSV51904909; called by muse, mutect2, varscan2
- SLC26A4 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as CM097063, COSV55919138; called by muse, mutect2, varscan2
- SLC4A2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs1476549849, COSV59658935; called by muse, mutect2, varscan2
- SLC8A3 | c.2036C>T p.T679M (on ENST00000381269 / NM_183002.3; = p.T677M on NM_033262.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145472014; called by muse, mutect2, varscan2
- SLC8A3 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63524969; called by muse, mutect2
- SMARCA2 | c.3604G>A p.G1202S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM122548, COSV61807248, COSV61811057; called by muse, mutect2, varscan2
- SNAI3 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.56); PolyPhen benign (0.086); catalogued as COSV60003317; called by muse, mutect2, varscan2
- SORCS3 | c.2106G>T p.Q702H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV63793599, COSV63793659, COSV63797555; called by muse, mutect2, varscan2
- SPATA5 | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV56782071; called by muse, mutect2, varscan2
- SPATS2L | c.842A>C p.E281A | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs200898346, COSV62351811; called by muse, mutect2, varscan2
- SPDYA | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV61857063; called by muse, mutect2, varscan2
- SPRY2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV65701686; called by muse, mutect2, varscan2
- SRPRB | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.811); catalogued as rs1318991496, COSV71749171; called by muse, mutect2, varscan2
- SRRM2 | c.7631C>T p.S2544F | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs199625043, COSV51941176; called by muse, mutect2, varscan2
- STXBP2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55405031; called by muse, mutect2, varscan2
- SVEP1 | c.2467G>C p.E823Q | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV57044618; called by muse, mutect2, varscan2
- SYK | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV101002437; called by muse, mutect2, varscan2
- SYT2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV66142794; called by muse, mutect2, varscan2
- TACC3 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV57559973; called by muse, mutect2, varscan2
- TBCK | c.2279C>T p.S760L (on ENST00000273980 / NM_001163436.4; = p.S697L on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV56761085; called by muse, mutect2, varscan2
- TCF4 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61891706; called by muse, mutect2, varscan2
- TFF3 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV52294925; called by muse, mutect2, varscan2
- TGIF1 | c.535G>C p.D179H (on ENST00000330513 / NM_001374396.1; = p.D199H on NM_003244.4) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV57909086; called by muse, mutect2, varscan2
- TIAM2 | c.3141C>A p.H1047Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs747483957, COSV59701156; called by muse, mutect2, varscan2
- TLL1 | c.2713C>A p.Q905K | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.981); catalogued as COSV50312248; called by muse, mutect2, varscan2
- TMED3 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100229953; called by muse, mutect2, varscan2
- TMEM145 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV100003710, COSV56627181; called by muse, mutect2, varscan2
- TMEM201 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.338); catalogued as COSV61052436; called by muse, mutect2, varscan2
- TMEM62 | c.1820T>G p.L607W | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53042486; called by muse, mutect2, varscan2
- TOX | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63842512; called by muse, mutect2, varscan2
- TRERF1 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV100550587, COSV100551278; called by muse, mutect2, varscan2
- TTN | c.96733G>C p.E32245Q (on ENST00000591111; = p.E24821Q on NM_003319.4) | Missense Mutation (SNP) | VAF 27/38 reads (71%) | PolyPhen probably damaging (0.993); catalogued as COSV60265653; called by muse, mutect2, varscan2
- TTN | c.26795C>T p.T8932M (on ENST00000591111; = p.T8005M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | PolyPhen benign (0.003); catalogued as rs745792278, COSV60026005, COSV60085709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT7 | c.4168G>C p.E1390Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.261); catalogued as COSV52895216, COSV52897484; called by muse, mutect2, varscan2
- TXNDC15 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.045); catalogued as COSV64380059; called by muse, mutect2, varscan2
- UAP1L1 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs748371851, COSV64306941; called by muse, mutect2, varscan2
- UPF2 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV62662796; called by muse, mutect2, varscan2
- USP24 | c.6757C>G p.Q2253E | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.83); PolyPhen benign (0.029); catalogued as COSV53775461; called by muse, mutect2, varscan2
- USP4 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 25/28 reads (89%) | catalogued as COSV55535018, COSV99649267; called by muse, mutect2, varscan2
- UTRN | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV62344068; called by muse, mutect2, varscan2
- VAV2 | c.1404G>C p.K468N (on ENST00000371850 / NM_001134398.2; = p.K463N on NM_003371.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV64084380; called by muse, mutect2, varscan2
- VN1R2 | c.1041G>T p.W347C | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59039320; called by muse, mutect2, varscan2
- VPS13D | c.3106C>T p.R1036W | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200357229, COSV50668221; called by muse, mutect2, varscan2
- VSIG4 | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 71/76 reads (93%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV101038369, COSV66074625; called by muse, mutect2, varscan2
- WAPL | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV53938945; called by muse, mutect2, varscan2
- WDR25 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58939072; called by muse, mutect2, varscan2
- WDR45B | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV101124431, COSV66408778; called by muse, mutect2, varscan2
- WIPF1 | c.566G>C p.S189T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs902785044, COSV55819103; called by muse, mutect2, varscan2
- ZBTB32 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1174603840, COSV52892083; called by muse, mutect2, varscan2
- ZEB2 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57963587, COSV57965883; called by muse, mutect2, varscan2
- ZFAT | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV64744035; called by muse, mutect2, varscan2
- ZFHX4 | c.3180G>C p.L1060F | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51487442; called by muse, mutect2
- ZFYVE28 | c.2429-1G>C p.X810_splice | Splice Site (SNP) | VAF 11/19 reads (58%) | catalogued as COSV52115792; called by muse, mutect2, varscan2
- ZNF142 | c.4840G>A p.D1614N (on ENST00000411696 / NM_001379660.1; = p.D1414N on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV68745079; called by muse, mutect2, varscan2
- ZNF160 | c.1586C>A p.A529E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV62000608; called by muse, mutect2, varscan2
- ZNF264 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99567216; called by muse, mutect2, varscan2
- ZNF488 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs782757012; called by muse, mutect2, varscan2
- ZNF510 | c.624G>C p.E208D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as COSV56298689, COSV99793760; called by muse, mutect2, varscan2
- ZNF549 | c.1651C>T p.H551Y (on ENST00000376233 / NM_001199295.2; = p.H538Y on NM_153263.2) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53727293; called by muse, mutect2, varscan2
- ZNF57 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV60984379; called by muse, mutect2, varscan2
- ZNF609 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as COSV58588438; called by muse, mutect2, varscan2
- ZNF610 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs753778393, COSV58346091; called by muse, mutect2, varscan2
- ZNF93 | c.1686G>C p.E562D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59377685; called by muse, mutect2, varscan2
- ZNHIT6 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV65327646; called by muse, mutect2, varscan2
- ELOVL7 | c.402dup p.V135Cfs*7 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel
- HK1 | c.1292_1293insTT p.R432* | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- HRNR | c.5471C>G p.S1824C | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.213); called by mutect2, varscan2
- PIBF1 | c.1482dup p.L495Ifs*10 | Frame Shift Ins (INS) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- SEC24B | c.137del p.P46Qfs*33 | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | called by mutect2, varscan2
- SOS1 | c.3211del p.S1071Vfs*17 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- TEKT2 | c.331del p.D111Mfs*7 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by pindel, varscan2
- TRAV23DV6 | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.348); called by muse, mutect2
- XPO4 | c.1351-5_1355del p.X451_splice | Splice Site (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ABHD13 | c.75C>T p.L25= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV65535333; called by muse, mutect2, varscan2
- ABL1 | c.1923C>T p.I641= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV59338058; called by muse, mutect2, varscan2
- ACOX3 | c.1596A>G p.K532= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV62713367; called by muse, mutect2, varscan2
- ACTR5 | c.1368C>T p.F456= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV54761878; called by muse, mutect2, varscan2
- ADAT1 | c.234G>A p.K78= | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as COSV57186197, COSV57188041; called by muse, mutect2, varscan2
- ADGRG7 | c.537C>T p.I179= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56297547; called by muse, mutect2, varscan2
- AKAP8L | c.1467C>G p.L489= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV68474274; called by muse, mutect2, varscan2
- ALMS1 | c.1797G>A p.L599= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs1210520363, COSV52518667; called by muse, mutect2, varscan2
- ATP9A | c.195C>T p.F65= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV58763395, COSV58770486; called by muse, varscan2
- ATP9A | c.123C>A p.V41= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV58770494; called by muse, varscan2
- ATRN | c.1896C>T p.F632= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV53532383; called by muse, mutect2, varscan2
- BBS10 | c.939G>A p.V313= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs770072752, COSV53887755; called by muse, mutect2, varscan2
- BOD1L1 | c.7419T>C p.D2473= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV50042505; called by muse, mutect2, varscan2
- C10orf90 | c.1489C>T p.L497= | Silent (SNP) | VAF 79/168 reads (47%) | catalogued as COSV52961680; called by muse, mutect2, varscan2
- C5AR1 | c.501G>A p.L167= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV61893125; called by muse, mutect2, varscan2
- CD300LF | c.423G>A p.L141= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV56898521; called by muse, mutect2, varscan2
- CHD1L | c.2151C>G p.L717= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV63615020; called by muse, mutect2, varscan2
- CHD6 | c.2145C>T p.L715= | Silent (SNP) | VAF 69/168 reads (41%) | catalogued as rs750576384, COSV58560975; called by muse, mutect2, varscan2
- CLIC3 | c.192C>T p.I64= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1036065231, COSV65406798; called by muse, mutect2, varscan2
- CLPP | c.594C>A p.I198= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV55537350, COSV99832179; called by muse, mutect2, varscan2
- CTNNA2 | c.1755C>T p.F585= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as rs755494251, COSV58135395; called by muse, mutect2, varscan2
- DDB2 | c.846C>T p.L282= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV57040259; called by muse, mutect2, varscan2
- DENND3 | c.1896G>A p.S632= | Silent (SNP) | VAF 91/118 reads (77%) | catalogued as rs755693084, COSV52804211; called by muse, mutect2, varscan2
- DMGDH | c.1662C>G p.L554= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV54865023, COSV54867528; called by muse, varscan2
- DSC3 | c.75C>T p.F25= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV64574739; called by muse, mutect2, varscan2
- ECT2L | c.2169C>T p.V723= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV62886424; called by muse, mutect2, varscan2
- FAM193A | c.762G>A p.R254= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV61197308; called by muse, mutect2, varscan2
- FBXW9 | c.1356C>T p.L452= (on ENST00000587955; = p.L432= on NM_032301.3) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV66710144, COSV66710383; called by muse, mutect2, varscan2
- GJB4 | c.558C>T p.F186= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV58356904; called by muse, mutect2, varscan2
- GMPR | c.717C>G p.V239= | Silent (SNP) | VAF 48/355 reads (14%) | catalogued as COSV52474836; called by muse, mutect2, varscan2
- GPX5 | c.228A>G p.T76= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV69079788; called by muse, mutect2, varscan2
- GTF3C1 | c.18G>C p.S6= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs143230097; called by muse, varscan2
- HAPLN4 | c.231C>T p.H77= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV52270822; called by muse, mutect2, varscan2
- HERPUD2 | c.1164C>T p.F388= | Silent (SNP) | VAF 52/80 reads (65%) | catalogued as COSV60946756; called by muse, mutect2, varscan2
- HHAT | c.867G>A p.A289= | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as rs375130305; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.199C>T p.L67= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV67335298, COSV99063646; called by muse, mutect2, varscan2
- KALRN | c.5988G>A p.K1996= (on ENST00000360013 / NM_001024660.4; = p.K299= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV52262483; called by muse, mutect2, varscan2
- KCNA1 | c.942C>A p.I314= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1565433417, COSV66836650, COSV66838396; called by muse, mutect2, varscan2
- KCTD13 | c.198C>G p.L66= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100442107; called by muse, mutect2
- KIF2B | c.1551T>C p.I517= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV52134293; called by muse, mutect2, varscan2
- KMT2A | c.2409G>A p.L803= | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as COSV63290754; called by muse, mutect2, varscan2
- KRT3 | c.1011C>T p.T337= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV58816754; called by muse, mutect2, varscan2
- KRT80 | c.744G>C p.L248= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV57551019; called by muse, mutect2, varscan2
- LAMB2 | c.4800G>A p.E1600= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV59736645; called by muse, mutect2, varscan2
- LATS1 | c.1132C>T p.L378= | Silent (SNP) | VAF 59/88 reads (67%) | catalogued as COSV53597585; called by muse, mutect2, varscan2
- LIPE | c.1866G>C p.L622= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54924737; called by muse, mutect2, varscan2
- LRAT | c.54C>G p.L18= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as COSV60476800, COSV60477874; called by muse, mutect2, varscan2
- MACROH2A2 | c.12G>A p.R4= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV64713566; called by muse, mutect2, varscan2
- MRTFA | c.876C>T p.L292= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100843973, COSV62935713; called by muse, mutect2, varscan2
- MUC6 | c.2961C>G p.L987= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV70147948; called by muse, mutect2, varscan2
- NCAN | c.486C>T p.F162= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV53056397; called by muse, mutect2, varscan2
- NCOA1 | c.627C>A p.T209= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV56041621, COSV56050944; called by muse, mutect2, varscan2
- NEIL3 | c.1455T>C p.S485= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV52812827, COSV99220412; called by muse, mutect2
- NUP205 | c.1185C>T p.L395= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV53664370; called by muse, mutect2, varscan2
- OLIG3 | c.402C>T p.I134= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV62989002; called by muse, mutect2, varscan2
- OTULINL | c.864G>C p.L288= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as COSV57034277, COSV57035780; called by muse, mutect2, varscan2
- P2RX7 | c.471G>A p.G157= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV55856989; called by muse, mutect2, varscan2
- PCDHB13 | c.213G>C p.G71= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs782130728; called by muse, mutect2, varscan2
- PCED1A | c.411G>C p.V137= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV100642910, COSV62314106; called by muse, mutect2, varscan2
- PER2 | c.276A>G p.P92= | Silent (SNP) | VAF 83/159 reads (52%) | catalogued as rs201214959, COSV54526597; called by muse, mutect2, varscan2
- PLPP5 | c.495C>T p.F165= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1287727042, COSV100395280; called by muse, mutect2
- PLSCR5 | c.363G>C p.L121= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV71648981, COSV71649176; called by muse, mutect2, varscan2
- PPP2R1B | c.42G>A p.A14= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV59537123; called by muse, mutect2
- PTPN14 | c.813C>T p.L271= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV65286993; called by muse, mutect2, varscan2
- RBM15 | c.387G>A p.P129= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1361545569, COSV63924194; called by muse, mutect2, varscan2
- RTKN2 | c.210G>A p.S70= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1252827376, COSV65681198; called by muse, mutect2, varscan2
- RXFP3 | c.894C>T p.R298= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100347497; called by muse, mutect2, varscan2
- SCN2A | c.1422C>T p.F474= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV51836851; called by muse, mutect2, varscan2
- SKI | c.354G>A p.E118= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101049302, COSV66014404; called by muse, mutect2, varscan2
- SLC22A10 | c.858G>A p.L286= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV60423066; called by muse, mutect2, varscan2
- SLC22A3 | c.765A>T p.I255= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV51715944; called by muse, mutect2, varscan2
- SLC2A1 | c.1107C>T p.I369= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs145962512; ClinVar: likely benign; called by muse, varscan2
- STXBP5 | c.12C>T p.F4= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs758263333, COSV99470095; called by muse, varscan2
- SUPT20HL1 | c.1776C>T p.F592= | Silent (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- THEMIS2 | c.417C>T p.L139= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1045846619, COSV61078298; called by muse, mutect2, varscan2
- TRIM2 | c.600C>T p.I200= (on ENST00000437508; = p.I227= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV58637549; called by muse, mutect2, varscan2
- TRIM6 | c.709C>T p.L237= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53478269; called by muse, mutect2, varscan2
- UBA52 | c.39C>T p.I13= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV55890326; called by muse, mutect2, varscan2
- UFSP1 | c.36G>A p.R12= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV53818933; called by muse, mutect2
- UGGT2 | c.4014G>T p.V1338= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100948651, COSV65077303; called by muse, mutect2
- VPS51 | c.2211C>G p.L737= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV54208970; called by muse, mutect2, varscan2
- WDR91 | c.357C>G p.L119= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV60371473; called by muse, mutect2, varscan2
- ADAR | c.-935G>A | 5'UTR (SNP) | VAF 43/54 reads (80%) | catalogued as rs1297318149, COSV52719579; called by muse, varscan2
- ARNT2 | c.*3514C>T | 3'UTR (SNP) | VAF 44/82 reads (54%) | catalogued as COSV100308916; called by muse, mutect2, varscan2
- CDKL1 | n.211G>C | RNA (SNP) | VAF 43/172 reads (25%) | called by muse, mutect2, varscan2
- CNOT1 | c.3523-832G>C | Intron (SNP) | VAF 48/74 reads (65%) | catalogued as COSV99800022; called by muse, mutect2, varscan2
- CXCL12 | c.266+856G>C | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as rs1266657828, COSV100638918, COSV100638959; called by muse, mutect2, varscan2
- DST | c.4297-3580G>A | Intron (SNP) | VAF 27/83 reads (33%) | catalogued as COSV55033570; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397545 G>C | 3'Flank (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- NACA | c.71-1288G>C | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as COSV63272109; called by muse, mutect2, varscan2
- RNF216 | c.202-109G>C | Intron (SNP) | VAF 31/91 reads (34%) | catalogued as COSV66292187; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 38/42 reads (90%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
